Somatic mutation profile of tumor specimen BA2886D (aliquot aq-BA2886D) from BEATAML1.0 case 2076, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myeloid sarcoma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.5 years (24,278 days).
Specimen BA2886D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aa8d7f7-a1b9-4b1d-884a-4ef29b7c917e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2165D (Solid Tissue Normal), aliquot aq-BA2165D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9493be8e-0ea2-4d5b-9db0-1d6e33a1958a

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Splice Region 1, Silent 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH18 | c.2867C>T p.T956M | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1410483393; called by muse, mutect2
- LRRC8B | c.1186C>A p.L396M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR10X1 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by mutect2, varscan2
- RAD21 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- RASA2 | c.325A>T p.K109* | Nonsense Mutation (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- TRPC4AP | c.2246G>T p.C749F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2
- WASHC2C | c.126C>A p.G42= | Splice Region (SNP) | VAF 3/54 reads (6%) | called by muse, mutect2
- WDFY3 | c.9185G>T p.G3062V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- HIF1A | c.2457C>A p.L819= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- FHL1 | c.*940T>A | 3'UTR (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- SH2D1A | c.-25G>C | 5'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
